Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OS, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OS-01A (Primary Tumor).

[page 1 of 3]
PAGE #: 2
SEX: F

ICA-0-3
adenocarcinoma, NOS 8140/3
Site: esophagus, distal third
C15.5

lw
10/9/12

PROCEDURE: SPHS

Poorly-differentiated adenocarcinoma with extensive necrosis. Clinical
Diagnosis: Esophageal cancer. Operative Procedure:

PROCEDURE: SPGD

1. "Proximal stomach distal esophagus". Received in formalin in a large container is a 6.5 cm long distal esophagus with a 6.5 x 4.2 x 1.3 cm attached proximal stomach. The adventitia is ragged. The mucosa of the esophagus is gray-white and prominently folded. The mucosa of the stomach is tan and rugated. The esophageal mucosa is remarkable for a 4.2 x 3.3 x 1.3 cm gray-tan necrotic lesion that is located at the esophageal gastric junction however the mid point of the tumor is 1.5 cm above the esophageal gastric junction. The tumor is 4.1 cm away the proximal margin of resection and 2.2 cm away from the gastric margin of resection. The tumor has a maximum depth of 0.3 cm and extends to the muscularis. The tumor is friable and mostly necrotic. Multiple possible lymph nodes are identified ranging up to 1.2 cm. The cut surface of the largest is gray-white. No other abnormalities are noted.

1A. Tumor to adjacent proximal normal.

1B. Tumor to adjacent distal.

~~1C and D. Tumor to deep.~~

1E and F. Additional esophageal gastric junction.

1G. Multiple possible lymph nodes.

1H and I. One bisected lymph node. each)

2. "Lesser curvature". Received in formalin in a small container is a 3.7 x 3.2 x 1.1 cm irregular portion of yellow fibroadipose tissue. Two possible lymph nodes are identified, 0.7 and 1.1 cm.

2A and B. One bisected lymph node each. Fat retained.

3. "Lesser curvature gastric node". Received in formalin in a small container is a 1.3 cm possible lymph node. Bisected.

4. "Celiac node". Received in formalin in a small container is a 1.1 cm

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F

possible lymph node. Bisected.

5. "Cervical esophago-gastric margin". Received in formalin in a small container is a 1.1 cm long segment of esophagus that is 2.2 cm in diameter. Staple line is present on one aspect with the other being left open. Tissue is removed from the staple line. Staple line retained.

PROCEDURE: SPMI

GASTROESOPHAGEAL JUNCTION

LOCATION: Gastroesophageal junction

SIZE: 4.2 cm

TYPE OF CARCINOMA: Adenocarcinoma not arising in Barrett's mucosa

DEPTH OF INVASION: Muscularis propria

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 1/13

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

T2 N1

PROCEDURE: SPDX

185. Distal esophagus and proximal stomach, resection: Invasive, ~~poorly-differentiated adenocarcinoma arising at the gastroesophageal junction~~ and invading into the muscularis propria (4.2 cm). No intestinal metaplasia. No vascular invasion. Margins negative. Metastatic carcinoma in one of nine lymph nodes (1/9).

2. Lymph nodes, lesser curvature of stomach, excision: Two lymph nodes negative for neoplasm (0/2).

3. Lymph node, lesser curvature of stomach, excision: One lymph node negative for neoplasm (0/1).

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: F

4. Lymph node, celiac, excision: One lymph node negative for neoplasm (0/1).

the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

TI/PAI Discrepancy		

10/9/12

Source: NCI Genomic Data Commons file afe2521e-17ab-4470-89c7-85d63a89c0f9 (TCGA-L5-A4OS.AA9D08D7-FBE8-448F-A8F1-31F253C452D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).